Gene-level copy-number profile of tumor specimen TCGA-DK-A3IL-01A from TCGA case TCGA-DK-A3IL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.5 years (29,047 days).
Specimen TCGA-DK-A3IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f7f26ac9-1948-4b37-bb94-c88d7fcf5599.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1146633b-a02d-46f9-882b-0943c1013a0e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 360; copy number 2: 11,738; copy number 3: 30,256; copy number 4: 12,536; copy number 5: 3,033; copy number 6: 1,713; copy number 7: 169; copy number 8: 3; copy number 9: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IL-01A-11D-A20B-01): tumor purity 0.74, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 184 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 7: AC010983.1.
- chr5:125,966,777–125,968,085, 1 gene, copy number 9: RPSAP37.
- chr7:93,482,760–93,484,019, 2 genes, copy number 8: MIR653, MIR489.
- chr11:54,591,480–57,918,239, 176 genes, copy number 7–9 (broad region; genes not listed).
- chr16:52,198,012–52,227,956, 1 gene, copy number 8 (within-gene range 4–8): AC007333.2.
- chr18:27,335,968–27,595,164, 1 gene, copy number 7 (within-gene range 2–7): AC090403.1.
- chr18:27,452,514–27,469,673, 2 genes, copy number 7: PA2G4P3, AC068408.2.

Autosomal genes at a single copy (total copy number 1): 360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
